Surgical pathology report (de-identified scan), TCGA case TCGA-VD-A8KG, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-A8KG-01A (Primary Tumor).

[page 1 of 4]
Department of Pathology

Page 1 of 4

REPORT Tel:

Clinical Consultant & Location

Sex

Unit No

This Copy For:

SPECIMEN

Right globe

CLINICAL DETAILS

Right eye floaters and visual field defect and flashes of light since
Seen at local eye unit and ultrasound was suggestive of collar-stud choroidal melanoma - referred to diagnosis confirmed. Tumour and exudative detachment. Largest diameter 11.34mm. Thickness 7.6mm. Post ora.

MACROSCOPIC DESCRIPTION

An intact right eye.

Dimensions: Axial 24.5mm, Horizontal 23mm, Vertical 23mm

Cornea: Horizontal 12mm, Vertical 11mm

Optic nerve
Length 4mm, Diameter 4mm

Pupil: regular, normal depth

On trans-illumination, a dark shadow seen inferior posteriorly measuring approximately 13 x 10mm, and 5mm from optic disc.

Plane of section: vertical

Intraocular description:

On opening, a dome shaped tumour is seen, pale and fragmented.
Height 7mm
LBD 12mm

MICROSCOPY

Sections show a focally pigmented choroidal melanoma with attached adjacent normal choroid and sclera and associated with exudative / haemorrhagic retinal detachment. The tumour consists predominantly of spindle cells. The number of

Reported:

Pathologist:

Electronically Verified:

ICD-6-3
Melanoma, spindle cell type B 8774/3
Site @ Choroid C69.3
9/11/14

[page 2 of 4]
Department of Pathology			Page 2 of 4
HISTOPATHOLOGY REPORT Tel:			
Surname [REDACTED]	Lab No [REDACTED]		Clinical Consultant & Location [REDACTED]
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For: [REDACTED]

mitosis is approximately 1/40 high power fields. The microvasculature of the melanoma is prominent, and closed loops are not present in the planes of section. The lymphocytic infiltrate within the tumour is minimal. Tumour necrosis is not seen. There is focal tumour extension into the sclera through a vascular channel. No evidence of tumour involvement is seen in sections from optic nerve or vortex veins examined. Tumour cells are not seen at the resection margins.

Elsewhere, the cornea shows no significant abnormality. The anterior chamber angles are open and the anterior chamber is deep. The iris shows no significant abnormality but the ciliary body appears atrophic with hyalinisation of ciliary processes. The lens shows subcapsular degenerative changes. Retina overlying the tumour is slightly atrophic and Bruch's membrane appears breached in the sections examined.

DIAGNOSIS

Right eye, enucleation: Choroidal melanoma of predominant spindle cell type.

COMMENT

Immunohistochemistry for assessment of expression of Melan-A and HSP27 by tumour cells will be performed.

Molecular genetic examination of DNA extracted from the tumour cells will be also carried out using multiplex-ligation dependent probe amplification (MLPA), looking at chromosomes 1, 3, 6 and 8. A supplementary report will follow in due course.

SUPPLEMENTARY REPORT

In the meantime, molecular genetic analysis of tumour DNA extracted from the fresh uveal melanoma tissue was performed using the technique termed multiplex ligation-dependent probe amplification (MLPA). These investigations were performed in the

Reported:

Pathologist:

Electronically Verified:

[page 3 of 4]
Department of Pathology

Page 3 of 4

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]
Forename(s) [REDACTED]	DOB/Age [REDACTED] Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]	

This Copy For: [REDACTED]

The kit P027B from [REDACTED] which examines for gains or losses in 31 loci on chromosomes 1, 3, 6 and 8, was used. The DNA concentration was measured using [REDACTED] and the quality assessed using multiplex-PCR prior to the MLPA reaction.

The DNA concentration was high and of good quality on assessment. The MLPA reaction was run at least twice on differing occasions, resulting in similar results.

The results of the sequence analysis of the MLPA products is printed on a separate report. In summary, sequence analysis demonstrated:

4 borderline losses on chromosome 1, 7 borderline losses in chromosome 3 (equating to chromosome 3 loss), gains of chromosome 6p, and gains of chromosome 8q.

These molecular data require correlation with the clinical and morphological data for metastatic risk assessment.

SUPPLEMENTARY AND FINAL REPORT

In the meantime immunohistochemistry was performed: the tumour cells demonstrate positivity for MelanA, BAP1 (cytoplasmic only), and HSP-27 (score 3).

COMMENT

SPECIMEN	2= Eye
TUMOUR PRESENT	Yes
TUMOUR TYPE	1= Melanoma
CELL TYPE	2= Spindle B
CT LOOPS	1= No closed loops
NECROSIS	No
PIGMENTATION	Yes
LYMPHOCYTIC INFILTRATION	No
MITOTIC FREQUENCY	1 /40 HPF

Reported:

Pathologist:

Electronically Verified:

[page 4 of 4]
Department of Pathology

Page 4 of 4

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED] [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]		Sex [REDACTED]
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For: [REDACTED]

DIFFUSE MELANOMA	No
SPREAD	2= Intra-scleral
CLEARANCE	2= Adequate
HSP-27 POSITIVITY	3= >70%
LARGE DIAMETER THICKNESS	11.3 mm 7.6 mm

Reported:

Pathologist:

Electronically Verified:

Source: NCI Genomic Data Commons file 35016fff-ed18-45a1-a5a1-20e0f5f33c8f (TCGA-VD-A8KG.A71F24D0-ADE3-4608-9941-47B025FD6A16.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).